Gene-level copy-number profile of tumor specimen TCGA-33-AASL-01A from TCGA case TCGA-33-AASL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.3 years (20,940 days).
Specimen TCGA-33-AASL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.86f0e70a-7f56-4fbe-ba21-06a63b9d6b28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-AASL-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7e129067-bbff-4d0d-ac87-6c1d49f41d9c

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 68; copy number 2: 254; copy number 3: 21,255; copy number 5: 1,787; copy number 6: 30,418; copy number 7: 4; copy number 9: 970; copy number 10: 3,845; copy number 11: 115; copy number 14: 991; copy number 16: 29; copy number 17: 12; copy number 27: 1; copy number 31: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-AASL-01A-11D-A400-01): tumor purity 0.43, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,137,093–11,771,350, 10 genes (within-gene range 0–5): HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr3:37,969,404–38,029,642, 4 genes: MIR26A1, VILL, PLCD1, Y_RNA.
- chr4:164,188,311–164,197,711, 2 genes: AC105250.1, ANP32C.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–3): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:87,659,613–87,863,533, 5 genes (within-gene range 0–3): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:102,591,524–102,918,335, 18 genes: RNU6-43P, AL391121.1, TRIM8, ARL3, SFXN2, WBP1L, RNU6-1231P, CYP17A1, PFN1P11, PTGES3P4, AL358790.1, BORCS7, BORCS7-ASMT, U6, AS3MT, RPL22P17, AL356608.3, AL356608.1.
- chr16:6,380,476–6,577,359, 2 genes: AC006112.1, AC007223.1.
- chr16:15,949,138–16,143,257, 2 genes (within-gene range 0–3): ABCC1, RPL17P40.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 1,037 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,228,726–175,810,548, 500 genes, copy number 14 (within-gene range 10–14) (broad region; genes not listed).
- chr3:175,609,479–198,222,513, 491 genes, copy number 14 (broad region; genes not listed).
- chr6:91,390,313–92,888,581, 16 genes, copy number 17–31: AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1.
- chr7:57,402,181–57,837,046, 29 genes, copy number 16: AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr8:31,219,894–31,220,984, 1 gene, copy number 27: KCTD9P6.

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
